Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6336, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6336-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. LEFT PELVIC LNODES
- B. PROSTATE

TCGA - G9 - 6336

SPECIMEN(S):

- A. LEFT PELVIC LNODES
- B. PROSTATE

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Lymph node, left pelvic, biopsy: Negative for tumor. By Dr., called to Dr.

GROSS DESCRIPTION:

A. LEFT PELVIC LYMPH NODES

Received fresh labeled with patient name designated "A - left pelvic lymph node" are multiple fragments of yellow-red adipose tissue measuring 4 x 3 x 1 cm in aggregate. Two possible lymph nodes are identified measuring 0.8 x 0.8 x 0.3 cm, and 0.3 x 0.2 x 0.2 cm. Both lymph nodes are submitted entirely for frozen section. The remainder of the specimen is submitted in cassettes A2 through A5.

B. PROSTATE

Received fresh labeled with patient name designated "B - prostate" is a resected prostate gland weighing 51 grams and measuring 5 cm from right to left, 4.3 cm from anterior to posterior, and 3.7 cm from apex to base. The external capsule is red, smooth and intact. The specimen is inked as follows: apex-red, anterior-orange, base-blue, posterior-black, right-green, left-yellow. The apex and base are disassembled from the specimen to yield a new weight of 21 grams. The specimen is serially sectioned from apex to base. Cut sections show tan-beige firm, fibrous parenchyma. The right seminal vesicle measures 2.4 x 2 x 0.5 cm and the left seminal vesicle measures 3.5 x 1.4 x 0.5 cm. Both are bisected to show beige-tan cystic tissue. Both the right and left vas deferens measure 5.5 cm in length by 0.5 cm in diameter, and 5 cm in length by 0.5 cm in diameter, respectively. Both right and left vas deferens are serially sectioned to show firm, beige tube-like structure. A portion of the specimen is submitted for tissue procurement and the remainder is entirely submitted for microscopic evaluation. Cassettes are submitted as follows:

- B1: level 1 right side
- B2: level 1 left side
- B3: level 2 right anterior
- B4: level 2 right posterior
- B5: level 2 left anterior
- B6: level 2 left posterior
- B7-B8: level 3 capsule, right side
- B9: level 3 capsule, left side
- B10-B11: right apex
- B12-B13: left apex
- B14-B16: right base with proximal urethral margin
- B17-B19: left base with proximal urethral margin
- B20-B21: right lateral base
- B22: left lateral base
- B23: right posterior base with root of right seminal vesicle and vas
- B24: left posterior base with root of left seminal vesicle and vas
- B25: section of right seminal vesicle and representative section of right vas
- B26: section of left seminal vesicle and representative section of left vas

DIAGNOSIS:

A. LYMPH NODES, LEFT PELVIC, DISSECTION:

- FIVE LYMPH NODES NEGATIVE FOR CARCINOMA (0/5).

B. PROSTATE, RADICAL PROSTATECTOMY:

- ADENOCARCINOMA OF PROSTATE, GLEASON GRADES 3+4 = 7/10
- RIGHT LATERAL SURGICAL MARGIN IS FOCALLY (3 MM) INVOLVED

BY CARCINOMA (SLIDE B7)

- SEE SYNOPSIS TEMPLATE

- HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA.
- PATCHY CHRONIC PROSTATITIS.

[page 2 of 2]
SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: B; PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 25%

Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Indeterminate

Note: PT2 + or PT 2 X is a proposed stage category where there is margin positivity, but no definitive histologic evidence of extraprostatic extension by carcinoma.

Reference: [REDACTED] Prostate Pathology, ASCP: 380, 2003

Bladder Neck Involved: No

Margins Involvement: Yes

Location: Right lateral margin.

Linear Distance: Focal (1-10mm)

Frozen Performed: No

Post Hormonal Therapy Change: No

Lymph Nodes: Negative Left 0 / 5

Other Pathologic Findings: BPH

Pathological Staging (pTNM): T 2+ N 0 M x

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Prostate ca

[REDACTED]

Source: NCI Genomic Data Commons file c9f30083-e9f8-4a8b-b378-bf630f21cef9 (TCGA-G9-6336.CEDA2FFB-B844-4F89-BABA-82A66E6F3F0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).